Somatic mutation profile of tumor specimen MMRF_2195_1_BM_CD138pos (aliquot MMRF_2195_1_BM_CD138pos_T1_KHS5U_L08795) from MMRF case MMRF_2195, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.0 years (25,569 days).
Specimen MMRF_2195_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c63323d0-f27d-4f2c-bc6e-21c3e5ddc594.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2195_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2195_1_PB_WBC_C3_KHS5U_L08763; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b21ba502-de2f-4a49-8cf3-6d47757a097b

The open-access MAF lists 135 somatic variants for this specimen: 51 protein-altering or splice-affecting, 16 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 44, Missense Mutation 44, Silent 16, Intron 11, Nonsense Mutation 5, 5'UTR 4, 5'Flank 4, RNA 3, 3'Flank 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 35/120 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- A2M | c.4141G>A p.V1381I | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.03); catalogued as rs753465099; called by muse, mutect2, varscan2
- A2M | c.1732C>A p.L578I | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100588553; called by muse, mutect2, varscan2
- ABCA13 | c.14662G>A p.D4888N | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1397241273; called by muse, mutect2, varscan2
- ATP1A2 | c.2344C>T p.P782S | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63404525; called by muse, mutect2, varscan2
- C12orf42 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as COSV100171860; called by muse, mutect2, varscan2
- CDKN1B | c.180G>A p.W60* | Nonsense Mutation (SNP) | VAF 41/112 reads (37%) | catalogued as COSV57429573, COSV57429709, COSV57430739; called by muse, mutect2, varscan2
- COL6A1 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs780638665; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CWC15 | c.332A>G p.D111G | Missense Mutation (SNP) | VAF 83/275 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.454); catalogued as rs1555096099; called by muse, mutect2, varscan2
- DMRTC2 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.123); catalogued as COSV54185821; called by muse, mutect2
- DST | c.9185C>A p.S3062* | Nonsense Mutation (SNP) | VAF 66/168 reads (39%) | catalogued as rs972168431; called by muse, varscan2
- KLHDC7A | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV68770484; called by muse, mutect2, varscan2
- LY75 | c.2827C>T p.P943S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as rs1411678225; called by muse, mutect2, varscan2
- MMP16 | c.947A>G p.D316G | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.09); catalogued as COSV54161252; called by mutect2, varscan2
- MTMR2 | c.1667A>G p.Y556C | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs147170889; called by muse, mutect2, varscan2
- MYH7 | c.5071G>A p.V1691M | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs45464193, CM031282, COSV62518813, COSV62521627; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSD2 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.104); catalogued as rs781460620; called by muse, mutect2, varscan2
- PTPRN2 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs779663542, COSV67057853; called by muse, mutect2, varscan2
- SLCO1C1 | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV56871656, COSV56876914; called by muse, mutect2, varscan2
- SYT4 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV54902913; called by muse, mutect2, varscan2
- TBC1D8 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as rs780603523; called by muse, mutect2, varscan2
- VPS13C | c.5116G>A p.V1706I (on ENST00000644861 / NM_020821.3; = p.V1663I on NM_017684.5) | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.125); catalogued as rs754917020; called by muse, mutect2, varscan2
- ZFAND2B | c.502A>G p.M168V | Missense Mutation (SNP) | VAF 48/435 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs777785598; called by muse, mutect2, varscan2
- ZSCAN18 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1330853622, COSV99559617; called by muse, mutect2, varscan2
- ADAMTS9 | c.3745T>A p.S1249T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARL4D | c.305A>G p.D102G | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP13A5 | c.356A>G p.N119S | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- BRPF1 | c.1197G>C p.Q399H | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYFIP2 | c.2984G>T p.G995V (on ENST00000616178 / NM_001291722.2; = p.G970V on NM_014376.4) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ENDOD1 | c.650del p.E217Gfs*30 | Frame Shift Del (DEL) | VAF 15/113 reads (13%) | called by mutect2, pindel, varscan2
- GFAP | c.1175del p.G392Afs*32 | Frame Shift Del (DEL) | VAF 49/173 reads (28%) | called by mutect2, pindel, varscan2
- GLDC | c.1864G>C p.E622Q | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAT1 | c.409A>T p.K137* | Nonsense Mutation (SNP) | VAF 11/136 reads (8%) | called by muse, mutect2
- HEATR4 | c.2858G>A p.R953H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- HELZ | c.230A>T p.D77V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MROH9 | c.357C>A p.Y119* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- NAT2 | c.841C>G p.P281A | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- NPTX2 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ODF2L | c.934C>G p.L312V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR10AG1 | c.709A>C p.I237L | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.009); called by muse, varscan2
- OR2AK2 | c.924G>A p.W308* | Nonsense Mutation (SNP) | VAF 43/193 reads (22%) | called by muse, varscan2
- PCK1 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLR1G | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.107); called by muse, varscan2
- PPP1R12A | c.2224G>C p.E742Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.047); called by muse, mutect2
- RNF183 | c.383C>G p.T128S | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.197); called by muse, varscan2
- SFSWAP | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPATA31D4 | c.2243G>T p.S748I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by mutect2, varscan2
- XAF1 | c.162C>A p.H54Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZFP82 | c.1300C>A p.L434I | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ZSCAN29 | c.2273G>T p.G758V | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACOT7 | c.624C>T p.N208= (on ENST00000377855 / NM_181864.3; = p.N198= on NM_007274.4) | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs767271021; called by muse, mutect2, varscan2
- CCDC63 | c.1116C>T p.H372= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as rs199829623, COSV57527568; called by muse, mutect2, varscan2
- CCDC9B | c.490C>T p.L164= | Silent (SNP) | VAF 38/389 reads (10%) | called by muse, mutect2
- CMTM4 | c.534C>T p.S178= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs370418115; called by muse, mutect2, varscan2
- DNHD1 | c.39T>C p.D13= | Silent (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- FSIP2 | c.10842A>G p.V3614= | Silent (SNP) | VAF 45/113 reads (40%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.465C>A p.V155= | Silent (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- H1-3 | c.198G>C p.A66= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as rs747596738, COSV55097044, COSV55098747; called by muse, mutect2
- ISM1 | c.234C>T p.H78= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as rs1231562991; called by muse, mutect2, varscan2
- LAMA3 | c.6753C>A p.T2251= (on ENST00000313654 / NM_198129.4; = p.T642= on NM_000227.6) | Silent (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2, varscan2
- MS4A14 | c.720T>A p.S240= | Silent (SNP) | VAF 61/325 reads (19%) | called by muse, mutect2, varscan2
- MYH4 | c.1455C>T p.N485= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as rs151236045; called by muse, mutect2, varscan2
- OR2W3 | c.171C>A p.T57= | Silent (SNP) | VAF 12/166 reads (7%) | catalogued as COSV100831830; called by muse, mutect2
- POLR2A | c.3555G>T p.V1185= | Silent (SNP) | VAF 61/172 reads (35%) | called by muse, mutect2, varscan2
- TACR2 | c.681C>A p.R227= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs1026288847; called by muse, varscan2
- ZCCHC17 | c.309T>C p.V103= | Silent (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- ACSL6 | chr5:131952313 G>T | 3'Flank (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- ADGRF3 | chr2:26308913 G>C | 3'Flank (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- AL121899.2 | c.*69C>A | 3'UTR (SNP) | VAF 15/151 reads (10%) | called by muse, mutect2
- AMER3 | c.*82G>T | 3'UTR (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- BMP6 | c.*1184_*1186del | 3'UTR (DEL) | VAF 27/83 reads (33%) | called by mutect2, pindel, varscan2
- BUD13 | c.*64G>A | 3'UTR (SNP) | VAF 51/198 reads (26%) | called by muse, mutect2, varscan2
- C17orf49 | chr17:7014639 C>G | 5'Flank (SNP) | VAF 27/134 reads (20%) | called by muse, mutect2, varscan2
- CCSER2 | c.*2174G>C | 3'UTR (SNP) | VAF 37/46 reads (80%) | called by muse, mutect2, varscan2
- EEA1 | c.*1867A>C | 3'UTR (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- EIF2B5 | chr3:184135246 A>T | 5'Flank (SNP) | VAF 27/120 reads (23%) | called by muse, mutect2, varscan2
- ENDOD1 | c.*1490A>G | 3'UTR (SNP) | VAF 21/132 reads (16%) | called by muse, mutect2, varscan2
- EPDR1 | c.*707C>T | 3'UTR (SNP) | VAF 38/141 reads (27%) | called by muse, mutect2, varscan2
- EXOC6B | c.*2140G>A | 3'UTR (SNP) | VAF 6/63 reads (10%) | catalogued as rs912927900; called by muse, mutect2
- FAM90A28P | n.1162A>G | RNA (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- FIBIN | c.*985C>T | 3'UTR (SNP) | VAF 12/78 reads (15%) | called by mutect2, varscan2
- FOSL2 | c.*4527A>G | 3'UTR (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- GRIK2 | c.*624T>G | 3'UTR (SNP) | VAF 31/78 reads (40%) | called by mutect2, varscan2
- H4C9 | c.*234C>T | 3'UTR (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- HDAC2 | c.*1098G>T | 3'UTR (SNP) | VAF 24/87 reads (28%) | called by muse, varscan2
- HOXA6 | chr7:27152626 A>G | 5'Flank (SNP) | VAF 50/80 reads (63%) | catalogued as rs1000446074; called by muse, mutect2, varscan2
- HTR1A | c.*97_*104del | 3'UTR (DEL) | VAF 17/126 reads (13%) | called by mutect2, pindel, varscan2
- KAZN | c.*2945G>C | 3'UTR (SNP) | VAF 14/111 reads (13%) | called by muse, mutect2, varscan2
- KCNMB3P1 | n.2197C>A | RNA (SNP) | VAF 56/152 reads (37%) | called by muse, mutect2, varscan2
- KLHL34 | c.*149A>C | 3'UTR (SNP) | VAF 21/70 reads (30%) | called by muse, mutect2, varscan2
- LIN28B | chr6:104940458 G>A | 5'Flank (SNP) | VAF 24/51 reads (47%) | catalogued as rs1481482488; called by muse, mutect2, varscan2
- LRRC19 | c.*1514T>C | 3'UTR (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- LRRC58 | c.*2282T>A | 3'UTR (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- LRRK1 | c.4915-57C>A | Intron (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- LRTM1 | c.-53A>C | 5'UTR (SNP) | VAF 76/265 reads (29%) | called by muse, mutect2, varscan2
- LSAMP | c.-417T>G | 5'UTR (SNP) | VAF 36/78 reads (46%) | called by muse, varscan2
- LSM8 | c.31+302_31+330del | Intron (DEL) | VAF 8/63 reads (13%) | called by mutect2, pindel, varscan2
- M6PR | c.*47G>C | 3'UTR (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- MAD2L2 | c.232-16del | Intron (DEL) | VAF 60/274 reads (22%) | catalogued as rs757684790; called by mutect2, varscan2
- MBOAT2 | c.*848C>G | 3'UTR (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- MFAP1 | c.*100G>A | 3'UTR (SNP) | VAF 36/175 reads (21%) | catalogued as COSV99980015; called by muse, mutect2, varscan2
- MS4A10 | c.*108C>T | 3'UTR (SNP) | VAF 17/119 reads (14%) | catalogued as rs977699432, COSV100382472; called by muse, mutect2, varscan2
- NAPSA | c.349+34G>T | Intron (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- NAV3 | c.*629C>A | 3'UTR (SNP) | VAF 10/45 reads (22%) | catalogued as rs1393212793; called by muse, mutect2, varscan2
- NNMT | c.*384G>T | 3'UTR (SNP) | VAF 10/107 reads (9%) | called by muse, mutect2
- NUP214 | c.-116del | 5'UTR (DEL) | VAF 10/114 reads (9%) | catalogued as rs772528549; called by mutect2, pindel
- OTULIN | c.*5620A>G | 3'UTR (SNP) | VAF 13/133 reads (10%) | called by muse, mutect2, varscan2
- PDE6D | c.265+156T>C | Intron (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- PENK | c.138+51G>A | Intron (SNP) | VAF 37/107 reads (35%) | catalogued as COSV100152371; called by muse, mutect2, varscan2
- PLCB1 | c.*348T>G | 3'UTR (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- RAD9B | c.*223T>C | 3'UTR (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- RCCD1 | c.950-27A>G | Intron (SNP) | VAF 16/70 reads (23%) | called by mutect2, varscan2
- RD3 | c.*1541A>G | 3'UTR (SNP) | VAF 25/48 reads (52%) | called by muse, mutect2, varscan2
- RGS7BP | c.*754del | 3'UTR (DEL) | VAF 24/130 reads (18%) | called by mutect2, varscan2
- RRP15 | c.*3940T>G | 3'UTR (SNP) | VAF 32/113 reads (28%) | called by muse, mutect2, varscan2
- RSPO2 | c.95-7896A>G | Intron (SNP) | VAF 48/120 reads (40%) | called by muse, mutect2, varscan2
- SACM1L | c.*882T>A | 3'UTR (SNP) | VAF 20/61 reads (33%) | called by muse, mutect2, varscan2
- SASH1 | c.1210-81A>C | Intron (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- SDK1 | c.*680C>A | 3'UTR (SNP) | VAF 38/119 reads (32%) | called by muse, mutect2, varscan2
- SF3A1 | c.*928G>C | 3'UTR (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- SMCHD1 | c.-77G>C | 5'UTR (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- SNORD116-16 | n.52A>G | RNA (SNP) | VAF 11/151 reads (7%) | called by muse, mutect2
- SORBS2 | c.3084+4586C>A | Intron (SNP) | VAF 28/113 reads (25%) | called by muse, mutect2, varscan2
- TCTEX1D1 | c.*856G>A | 3'UTR (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
- TRIM23 | c.*232A>T | 3'UTR (SNP) | VAF 58/234 reads (25%) | called by muse, mutect2, varscan2
- TRIM23 | c.*109_*110insAATATA | 3'UTR (INS) | VAF 24/181 reads (13%) | called by pindel, varscan2
- TRIM23 | c.*16T>C | 3'UTR (SNP) | VAF 78/323 reads (24%) | called by muse, varscan2
- TRIM39 | c.*496_*498del | 3'UTR (DEL) | VAF 12/66 reads (18%) | catalogued as rs1467380388; called by pindel, varscan2
- TSLP | c.*1010T>C | 3'UTR (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- UNC5C | c.*2674A>G | 3'UTR (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- WDR59 | c.105-2819G>A | Intron (SNP) | VAF 15/24 reads (63%) | catalogued as rs1256044499; called by muse, mutect2, varscan2
- XCR1 | c.*2568dup | 3'UTR (INS) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- ZKSCAN1 | c.*3164C>T | 3'UTR (SNP) | VAF 5/35 reads (14%) | called by mutect2, varscan2
- ZNF710 | c.*1379C>A | 3'UTR (SNP) | VAF 75/251 reads (30%) | called by muse, mutect2, varscan2
